Gene-level copy-number profile of tumor specimen HCM-BROD-0041-C64-01A from HCMI case HCM-BROD-0041-C64, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: female; Vital status: Alive; Primary diagnosis: Nephroblastoma, NOS; Tissue or organ of origin: Kidney, NOS; Age at diagnosis: 7.3 years (2,655 days).
Specimen HCM-BROD-0041-C64-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file f44998ea-ef60-49e2-85b9-63e996bcd3e1.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HCM-BROD-0041-C64-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,228 have no estimate.
https://portal.gdc.cancer.gov/files/efddd2e6-a829-478a-af0a-66a039da47d9

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 37; copy number 1: 19,240; copy number 2: 37,227; copy number 3: 1,465; copy number 4: 268; copy number 5: 106; copy number 6: 5; copy number 10: 3; copy number 11: 18; copy number 13: 21; copy number 14: 5.

Homozygous deletions (total copy number 0; autosomes only): 37 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:248,548,756–248,565,299, 3 genes: AC098483.1, OR2AS1P, OR2T29.
- chr9:64,878,790–64,889,063, 2 genes: AC125634.1, RNU6-1293P.
- chr17:18,450,244–18,506,313, 6 genes: KRT16P4, AL353997.1, AL353997.4, TNPO1P2, LGALS9C, NOS2P2.
- chr21:7,744,962–8,454,792, 26 genes: SMIM11B, FAM243B, SMIM34B, KCNE1B, CU633980.1, FP671120.5, FP671120.4, MIR6724-1, FP671120.1, MIR3648-1, FP671120.2, FP671120.6, RNA5-8SN2, MIR6724-2, FP671120.3, FP671120.7, 5_8S_rRNA, FP236383.3, MIR6724-3, FP236383.1, FP236383.4, RNA5-8SN3, MIR6724-4, FP236383.2, FP236383.5, RNA5-8SN1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 158 genes in 12 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr14:19,954,490–19,957,996, 1 gene, copy number 5: OR4K16P.
- chr14:20,256,558–20,305,960, 2 genes, copy number 5 (within-gene range 4–5): TTC5, AL356019.2.
- chr14:20,365,667–20,461,465, 8 genes, copy number 5: TEP1, RNA5SP382, KLHL33, AL355075.5, OSGEP, AL355075.2, APEX1, PIP4P1.
- chr14:20,720,742–20,892,348, 10 genes, copy number 5: RANBP20P, EDDM3DP, EDDM3A, EDDM3B, RNASE6, AL133371.2, RNASE1, AL133371.3, AL133371.1, RNASE3.
- chr14:21,016,763–21,070,872, 8 genes, copy number 5 (within-gene range 4–5): NDRG2, MIR6717, TPPP2, AL161668.4, AL161668.2, RNASE13, RNASE7, RNASE8.
- chr14:21,829,539–21,853,006, 4 genes, copy number 5: TRAV11, TRAV12-1, TRAV8-2, TRAV8-3.
- chr14:21,894,433–22,168,988, 28 genes, copy number 5: TRAV8-4, TRAV8-5, TRAV13-2, TRAV14DV4, TRAV9-2, TRAV15, AC245505.1, TRAV12-3, TRAV8-6, TRAV16, TRAV17, TRAV18, TRAV19, AC245505.2, TRAV20, TRAV21, AC245505.3, TRAV22, TRAV23DV6, TRDV1, TRAV24, TRAV25, TRAV26-1, TRAV8-7, TRAV27, TRAV28, TRAV29DV5, TRAV30.
- chr14:22,197,446–22,482,959, 1 gene, copy number 5 (within-gene range 4–6): AC244502.1.
- chr14:22,207,522–22,488,652, 33 genes, copy number 5 (within-gene range 5–6): TRAV34, TRAV35, TRAV36DV7, TRAV37, TRAV38-1, TRAV38-2DV8, TRAV39, TRAV40, TRAV41, AC244502.2, AC244502.3, TRDV2, TRDD1, TRDD2, TRDD3, TRDJ1, TRDJ4, TRDJ2, TRDJ3, TRDC, TRDV3, TRAJ61, TRAJ60, TRAJ59, TRAJ58, TRAJ57, TRAJ56, TRAJ55, TRAJ54, TRAJ53, TRAJ52, TRAJ51, TRAJ50.
- chr14:22,547,506–22,552,156, 1 gene, copy number 5: TRAC.
- chr14:22,595,808–23,509,862, 57 genes, copy number 5–14: AC243965.2, ABHD4, OR6J1, AL160314.1, AL160314.2, OR6E1P, AL160314.3, AL135998.1, OXA1L, SLC7A7, MRPL52, MMP14, Y_RNA, Y_RNA, LRP10, REM2, RBM23, PRMT5-AS1, PRMT5, AL132780.1, HAUS4, AL132780.3, MIR4707, AJUBA, AL132780.2, C14orf93, AL132780.5, PSMB5, AL132780.4, PSMB11, CDH24, ACIN1, C14orf119, LMLN2, CEBPE, SLC7A8, RNU6-1138P, RNF212B, AL049829.1, RNU6-1046P, HOMEZ, H3P37, PPP1R3E, BCL2L2, BCL2L2-PABPN1, PABPN1, SLC22A17, EFS, AL049829.2, IL25, CMTM5, MYH6, MIR208A, MYH7, AL132855.1, MIR208B, NGDN.
- chr21:8,759,077–8,880,976, 5 genes, copy number 6: LINC01666, CR381670.2, SNX18P10, MTCO1P1, CR381670.1.

Autosomal genes at a single copy (total copy number 1): 16,963. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
